Somatic mutation profile of tumor specimen 0DKZ8N from CCDI case PBBYUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.3 years (477 days).
Specimen 0DKZ8N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 977098f3-0e92-4139-b78e-6ac0c99aab27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKZ8H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e0663f-3252-4019-9168-e19c199cf7f5

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL7 | c.175C>T p.R59C (on ENST00000339077 / NM_001031710.3; = p.R11C on NM_018846.5) | Missense Mutation (SNP) | VAF 183/592 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59165102; called by muse, mutect2, varscan2
- LSM11 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 43/812 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs769993241, COSV53847485; called by muse, mutect2
- SRGAP2 | c.3016G>A p.A1006T (on ENST00000624873 / NM_001170637.4; = p.A1007T on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/1024 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs536473733, COSV55340239; called by muse, mutect2
- PRPF4B | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 42/731 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.434); called by muse, mutect2
- B4GALNT2 | c.1254G>C p.L418= | Silent (SNP) | VAF 236/717 reads (33%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.69G>T p.L23= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as rs781885003; called by muse, mutect2, varscan2
- RPRD1B | c.379C>T p.L127= | Silent (SNP) | VAF 213/629 reads (34%) | called by muse, mutect2, varscan2
- ABCA4 | c.-94G>C | 5'UTR (SNP) | VAF 10/104 reads (10%) | catalogued as rs113514871; called by muse, mutect2
